Somatic mutation profile of tumor specimen BA2867D (aliquot aq-BA2867D) from BEATAML1.0 case 2116, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with mutated CEBPA; Tissue or organ of origin: Bone marrow; Age at diagnosis: 78.7 years (28,756 days).
Specimen BA2867D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5b041eda-3d99-4945-bf67-347dfc508042.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2949D (Solid Tissue Normal), aliquot aq-BA2949D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b9c34822-21d0-4073-a51b-6b1c9f3e0c2c

The open-access MAF lists 19 somatic variants for this specimen: 16 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Frame Shift Ins 2, Silent 2, 5'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SRSF2 | c.284C>A p.P95H | Missense Mutation (SNP) | VAF 9/24 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as rs751713049, CM1511359, COSV57969809, COSV57969816, COSV57969830; called by muse, mutect2, varscan2
- HECW1 | c.1573C>T p.R525W | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.619); catalogued as rs1562984403, COSV67835102; called by muse, mutect2
- MAN2C1 | c.2866G>A p.V956I | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.57); PolyPhen benign (0.228); catalogued as rs201870425; called by muse, mutect2, varscan2
- SYNE1 | c.3731C>G p.S1244C (on ENST00000367255 / NM_182961.4; = p.S1251C on NM_033071.3) | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.501); catalogued as COSV54901885, COSV54998361; called by muse, mutect2, varscan2
- TMEM132D | c.723G>T p.R241S | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV70610746; called by muse, mutect2, varscan2
- CCPG1 | c.1928T>C p.L643P | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.015); called by muse, mutect2
- CEBPA | c.988C>T p.Q330* | Nonsense Mutation (SNP) | VAF 87/233 reads (37%) | called by muse, mutect2, varscan2
- DCDC1 | c.2477C>G p.P826R | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.035); called by muse, varscan2
- DCDC1 | c.1642C>G p.L548V | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- DOCK4 | c.3781C>G p.Q1261E | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.017); called by muse, varscan2
- GFRA1 | c.931C>G p.P311A | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIF26B | c.626C>A p.A209D | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.068); called by muse, mutect2
- KLHDC7A | c.442G>A p.A148T | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- PRRG4 | c.239G>T p.R80I | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RUNX1 | c.1064dup p.P356Afs*217 (on ENST00000344691 / NM_001001890.3; = p.P383Afs*217 on NM_001754.5) | Frame Shift Ins (INS) | VAF 22/63 reads (35%) | called by mutect2, pindel, varscan2
- TET2 | c.3865delinsACC p.C1289Tfs*75 | Frame Shift Ins (INS) | VAF 23/48 reads (48%) | called by pindel, varscan2*
- GOLPH3 | c.120G>T p.A40= | Silent (SNP) | VAF 4/63 reads (6%) | called by muse, mutect2
- KSR1 | c.2757C>A p.G919= | Silent (SNP) | VAF 3/28 reads (11%) | catalogued as COSV52032923; called by muse, mutect2
- AP3S1 | chr5:115841648 G>A | 5'Flank (SNP) | VAF 14/50 reads (28%) | catalogued as rs1313388618; called by muse, varscan2
